Somatic mutation profile of tumor specimen TCGA-AX-A05Y-01A (aliquot TCGA-AX-A05Y-01A-11W-A027-09) from TCGA case TCGA-AX-A05Y, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 57.2 years (20,904 days).
Specimen TCGA-AX-A05Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df7e041b-ee80-49cd-95a8-655028e7cfb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A05Y-11A (Solid Tissue Normal), aliquot TCGA-AX-A05Y-11A-11D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9fbb3ba-6846-4879-ae73-9218f75651c0

The open-access MAF lists 235 somatic variants for this specimen: 175 protein-altering or splice-affecting, 51 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 51, Frame Shift Del 29, Nonsense Mutation 11, Frame Shift Ins 6, Intron 5, Splice Region 4, Splice Site 3, In Frame Del 2, 3'UTR 2, RNA 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 119/243 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 242/567 reads (43%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- JAG1 | c.1205dup p.Q403Tfs*13 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs35615084; ClinVar: pathogenic; called by pindel, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 75/173 reads (43%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 142/314 reads (45%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.1027-1G>A p.X343_splice | Splice Site (SNP) | VAF 33/71 reads (46%) | hotspot (GDC flag); catalogued as rs1057517809, CS1413088, COSV64290834, COSV64293694, COSV64298429; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 69/180 reads (38%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2489+2T>A p.X830_splice | Splice Site (SNP) | VAF 64/149 reads (43%) | hotspot (GDC flag); catalogued as COSV57300624, COSV57332429; called by muse, mutect2, varscan2
- ABCB5 | c.2140G>A p.A714T (on ENST00000404938 / NM_001163941.2; = p.A269T on NM_178559.6) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV51705917; called by muse, mutect2, varscan2
- ABCB6 | c.1386G>A p.T462= | Splice Region (SNP) | VAF 12/25 reads (48%) | catalogued as rs778740925, COSV54694246; called by muse, mutect2, varscan2
- ABCD3 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV100239061; called by muse, mutect2
- ACADVL | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs753377608, COSV50035106; called by muse, mutect2
- ACSBG2 | c.738C>T p.N246= | Splice Region (SNP) | VAF 80/190 reads (42%) | catalogued as rs560299046, COSV53123538; called by muse, mutect2, varscan2
- AHNAK | c.10565C>T p.P3522L | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs779201811, COSV57207766; called by muse, mutect2, varscan2
- ALG8 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 83/209 reads (40%) | catalogued as COSV55199681; called by muse, mutect2, varscan2
- AMOTL2 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1475311303, COSV51438344; called by muse, mutect2, varscan2
- APOC3 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.283); catalogued as rs201803883, CM125472, COSV52635483, COSV52636768; called by muse, mutect2, varscan2
- ARID1A | c.6511_6513dup p.L2171dup | In Frame Ins (INS) | VAF 51/126 reads (40%) | catalogued as COSV99055474; called by mutect2, pindel, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 28/54 reads (52%) | catalogued as rs753865255; called by mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 75/242 reads (31%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASIC1 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.086); catalogued as rs373616682; called by muse, mutect2, varscan2
- ATP1A2 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775979950, COSV63401983; called by muse, mutect2, varscan2
- ATP8B1 | c.2503C>T p.R835W | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.536); catalogued as rs371879699; called by muse, mutect2, varscan2
- B4GALT5 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 204/484 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs202087682, COSV65493106; called by muse, mutect2, varscan2
- BCAN | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs775100384, COSV61255937; called by muse, varscan2
- BCORL1 | c.3268C>T p.R1090* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV54389244; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as rs768244116; called by pindel, varscan2
- BNC2 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1346486985, COSV66143090; called by muse, mutect2, varscan2
- BRD8 | c.2404C>T p.R802* (on ENST00000254900 / NM_139199.2; = p.R875* on NM_006696.4) | Nonsense Mutation (SNP) | VAF 164/352 reads (47%) | catalogued as rs774763516, COSV50146058; called by muse, mutect2, varscan2
- C2CD3 | c.2198T>C p.L733P | Missense Mutation (SNP) | VAF 141/319 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV58091295; called by muse, mutect2, varscan2
- CAD | c.4772C>T p.A1591V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150612806; called by muse, mutect2, varscan2
- CADPS | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs147087123; called by muse, mutect2, varscan2
- CCSER1 | c.998A>G p.E333G | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV100395589; called by muse, mutect2
- CCT5 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 17/626 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.155); catalogued as rs1199077485, COSV99725579; called by muse, mutect2
- CD160 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 275/933 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs782335728, COSV52522899; called by muse, mutect2, varscan2
- CDH4 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs865878611, COSV64646292; called by muse, mutect2, varscan2
- CENPL | c.848T>C p.F283S | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61891643; called by muse, mutect2, varscan2
- CHD8 | c.5314C>T p.R1772C (on ENST00000646647 / NM_001170629.2; = p.R1493C on NM_020920.4) | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1286064384, COSV63036586; called by muse, mutect2, varscan2
- CLK2 | c.1078C>A p.Q360K (on ENST00000368361 / NM_001294339.2; = p.Q359K on NM_003993.4) | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100226903; called by muse, mutect2
- CNTNAP1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV52848778; called by muse, mutect2, varscan2
- CSPG4 | c.3100C>T p.R1034W | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs770213957; called by muse, mutect2
- CSPP1 | c.3694C>T p.R1232C (on ENST00000676605; = p.R1191C on NM_024790.6) | Missense Mutation (SNP) | VAF 53/359 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs759903681, COSV51581726; called by muse, mutect2, varscan2
- CTCF | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 14/482 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50474161; called by muse, mutect2
- CUL2 | c.1850T>C p.L617S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66078695; called by muse, mutect2, varscan2
- CUL9 | c.6355G>A p.D2119N | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.75); catalogued as rs763494466, COSV52726681; called by muse, mutect2, varscan2
- CYP4V2 | c.599T>C p.I200T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101114981; called by muse, mutect2
- DHX36 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100273925; called by muse, mutect2
- DHX40 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV52066644; called by muse, mutect2, varscan2
- DHX57 | c.2195del p.L732Wfs*7 | Frame Shift Del (DEL) | VAF 51/98 reads (52%) | catalogued as rs749610132; called by mutect2, varscan2
- DMP1 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 149/313 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV56819116; called by muse, mutect2, varscan2
- DNAH3 | c.8747C>T p.A2916V | Missense Mutation (SNP) | VAF 12/474 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.16); catalogued as COSV99770240; called by muse, mutect2
- DNAH7 | c.2851C>T p.R951* | Nonsense Mutation (SNP) | VAF 35/302 reads (12%) | catalogued as rs764315694, COSV56756820; called by muse, mutect2, varscan2
- DNMT3A | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs1459396018, COSV53044586; called by muse, mutect2, varscan2
- DUSP23 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV100929148; called by muse, mutect2
- EPO | c.159G>A p.T53= | Splice Region (SNP) | VAF 16/30 reads (53%) | catalogued as rs747340501, COSV53161196; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 21/116 reads (18%) | catalogued as rs775950025; called by mutect2, varscan2
- FBN2 | c.4594G>T p.D1532Y | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52500653; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 65/225 reads (29%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FUT3 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771268621, COSV54604935; called by muse, mutect2
- GAD1 | c.1631C>G p.A544G | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV64025255; called by muse, mutect2, varscan2
- GCNT3 | c.815T>C p.V272A | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101251867; called by muse, mutect2
- GLMN | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV64860041; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2456G>A p.G819D | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.691); catalogued as COSV63100187; called by muse, mutect2, varscan2
- H4C13 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV60693450; called by muse, mutect2, varscan2
- HECW2 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV53653252; called by muse, mutect2, varscan2
- IDNK | c.452A>G p.Q151R | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99462038; called by muse, mutect2
- IPO9 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1157160147, COSV64234766; called by muse, mutect2, varscan2
- IRAK1BP1 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV64048005; called by muse, mutect2, varscan2
- IRF2 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 6/120 reads (5%) | catalogued as COSV101165902; called by muse, mutect2
- ISLR2 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62301644; called by muse, mutect2, varscan2
- ITPR2 | c.7250del p.L2417* | Frame Shift Del (DEL) | VAF 25/224 reads (11%) | catalogued as rs1288961144; called by mutect2, pindel
- JAK2 | c.3313T>G p.C1105G | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67593456; called by muse, mutect2, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | catalogued as rs749990720; called by mutect2, varscan2
- KRTAP19-1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 260/575 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs199797669, COSV66860928, COSV66861078; called by muse, mutect2, varscan2
- LAMA1 | c.5872C>A p.L1958I | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV67533901; called by muse, mutect2, varscan2
- LAMA2 | c.4223G>A p.R1408H | Missense Mutation (SNP) | VAF 106/237 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs751858884, COSV70342677; called by muse, mutect2, varscan2
- LGR4 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); catalogued as COSV64863619; called by muse, mutect2, varscan2
- LMX1A | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as rs778377042, COSV54218498, COSV54225933; called by muse, mutect2, varscan2
- LRP1 | c.7079G>A p.R2360Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54505494; called by muse, mutect2, varscan2
- LRP1 | c.11908G>A p.G3970R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs1309594578, COSV54505506; called by muse, mutect2, varscan2
- LRRC4B | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV65350474; called by muse, mutect2, varscan2
- LRRK2 | c.4502G>A p.R1501Q | Missense Mutation (SNP) | VAF 154/308 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs904409907, COSV54147815; called by muse, mutect2, varscan2
- MOB3C | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99596443; called by muse, mutect2
- MTHFD1L | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs570312042, COSV66224439, COSV66228190; called by muse, mutect2, varscan2
- MUC16 | c.16693G>A p.V5565I | Missense Mutation (SNP) | VAF 78/690 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750565064, COSV67453893; called by muse, mutect2, varscan2
- NAV3 | c.562C>A p.H188N | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV57069071; called by muse, mutect2, varscan2
- NCL | c.750C>A p.D250E | Missense Mutation (SNP) | VAF 125/290 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59545316; called by muse, mutect2, varscan2
- NCOA1 | c.487G>T p.G163W | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56051311, COSV99946965; called by muse, mutect2
- NDUFA6 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 6/178 reads (3%) | catalogued as rs969146834; called by muse, mutect2
- NKTR | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 120/256 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs536150678, COSV51769497; called by muse, mutect2, varscan2
- NOD2 | c.500G>A p.C167Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (1); PolyPhen possibly damaging (0.899); catalogued as COSV56049131; called by muse, mutect2, varscan2
- NOP58 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 141/310 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs541358227, COSV51896028; called by muse, varscan2
- OGDHL | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs575253550, COSV65100800; called by muse, mutect2, varscan2
- OLFML2A | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368549348; called by muse, mutect2, varscan2
- OR4D5 | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 145/302 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58306144; called by muse, mutect2, varscan2
- PACS1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57696983; called by muse, mutect2, varscan2
- PCGF2 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1378038012; called by muse, mutect2, varscan2
- PCSK5 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 114/230 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs772577264, COSV65085619; called by muse, mutect2
- PDE10A | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63049893; called by muse, mutect2
- PELI2 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145879985; called by muse, mutect2
- PHC2 | c.2078C>T p.A693V (on ENST00000257118 / NM_198040.2; = p.A158V on NM_004427.4) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs765062816, COSV57102710; called by muse, mutect2, varscan2
- PLAGL2 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs145582553; called by muse, mutect2, varscan2
- PLIN4 | c.3698G>A p.R1233H (on ENST00000301286; = p.R1248H on NM_001367868.2) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs747359789, COSV56681768; called by muse, mutect2, varscan2
- PLXNC1 | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51571809; called by muse, mutect2, varscan2
- PMS1 | c.2766del p.H923Ifs*3 | Frame Shift Del (DEL) | VAF 40/109 reads (37%) | catalogued as COSV59719687; called by mutect2, pindel, varscan2
- POSTN | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200646973, COSV65712342; called by muse, mutect2, varscan2
- PRPF39 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217011877, COSV63276629; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 130/270 reads (48%) | catalogued as rs781858060; called by mutect2, varscan2
- PTPRD | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 236/505 reads (47%) | catalogued as COSV61934311, COSV61944518; called by muse, mutect2, varscan2
- PTPRG | c.4160A>G p.N1387S | Missense Mutation (SNP) | VAF 128/272 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs1427575715, COSV55633615; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 101/205 reads (49%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM26 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57392688; called by muse, mutect2, varscan2
- RCN3 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV54541592; called by muse, mutect2, varscan2
- RICTOR | c.448G>C p.V150L | Missense Mutation (SNP) | VAF 190/371 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as COSV57119089; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRP1B | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.438); catalogued as rs774996157, COSV61478669; called by mutect2, varscan2
- RUBCN | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs753948060, COSV56363933, COSV99584320; called by muse, mutect2, varscan2
- RUNX1T1 | c.641A>G p.H214R (on ENST00000265814 / NM_001198628.1; = p.H187R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99754521; called by muse, mutect2
- SAMD4B | c.2001G>T p.E667D | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.935); catalogued as COSV55393123; called by muse, mutect2, varscan2
- SCNN1G | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.092); catalogued as rs148179456; called by muse, mutect2, varscan2
- SEPTIN9 | c.601G>A p.A201T (on ENST00000427177 / NM_001113491.2; = p.A183T on NM_006640.4) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs201705602; called by muse, mutect2, varscan2
- SETX | c.5786C>T p.A1929V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.204); catalogued as rs200571606, COSV56394824; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- SHC3 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.498); catalogued as rs756796666, COSV65437292; called by muse, mutect2, varscan2
- SIKE1 | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 8/171 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV99285395; called by muse, mutect2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 212/716 reads (30%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC24A3 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as rs150292821; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 56/124 reads (45%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC9A6 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV100857945; called by muse, mutect2
- SMARCD2 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 42/81 reads (52%) | catalogued as rs1025863088, COSV56738394; called by muse, mutect2, varscan2
- SNRNP70 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.137); catalogued as COSV55505235; called by muse, mutect2, varscan2
- SPANXN1 | c.170G>T p.R57M | Missense Mutation (SNP) | VAF 481/1050 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV65122074; called by muse, mutect2, varscan2
- STARD10 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV58324800; called by muse, mutect2, varscan2
- TBC1D31 | c.1893dup p.H632Sfs*5 | Frame Shift Ins (INS) | VAF 40/92 reads (43%) | catalogued as rs768246273; called by mutect2, varscan2
- TBX20 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1160642834, COSV68783093; called by muse, mutect2, varscan2
- TET1 | c.5776C>T p.P1926S | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); catalogued as rs867902572, COSV101018832; called by muse, mutect2
- TMEM65 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV52629804; called by muse, mutect2, varscan2
- TNPO3 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs534068313, COSV55279372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TPP2 | c.2628+2T>C p.X876_splice | Splice Site (SNP) | VAF 12/112 reads (11%) | catalogued as COSV65751594; called by muse, mutect2, varscan2
- TRAPPC11 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745311754, COSV58216038; called by muse, mutect2
- TRRAP | c.5683G>A p.A1895T (on ENST00000359863 / NM_001244580.1; = p.A1877T on NM_003496.3) | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV62841341; called by muse, mutect2, varscan2
- TSPAN17 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs759956032, COSV53779543; called by muse, mutect2, varscan2
- TTN | c.57857G>A p.R19286H (on ENST00000591111; = p.R11862H on NM_003319.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | PolyPhen benign (0.017); catalogued as rs397517652, COSV59949524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TVP23A | c.420dup p.S141* | Frame Shift Ins (INS) | VAF 36/88 reads (41%) | catalogued as rs760251146; called by mutect2, varscan2
- UNC13B | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751894353, COSV65932638; called by muse, mutect2, varscan2
- USH2A | c.9080A>C p.E3027A | Missense Mutation (SNP) | VAF 111/360 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56343083; called by muse, mutect2, varscan2
- USP5 | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV57536079; called by muse, mutect2, varscan2
- VSIG10 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs777174568, COSV63652531; called by muse, mutect2, varscan2
- WDR61 | c.13-3del | Splice Region (DEL) | VAF 20/63 reads (32%) | catalogued as rs1159789858; called by mutect2, pindel, varscan2
- YIF1B | c.530C>T p.T177I (on ENST00000339413 / NM_001039673.3; = p.T162I on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.999); catalogued as COSV56649982; called by muse, mutect2, varscan2
- ZBTB21 | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762954242, COSV60403542; called by muse, mutect2, varscan2
- ZNF365 | c.885G>C p.Q295H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV67925199; called by muse, mutect2, varscan2
- ZNF394 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 61/142 reads (43%) | catalogued as rs1484638678, COSV58742285; called by muse, mutect2, varscan2
- ZNF496 | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs145725779; called by muse, mutect2, varscan2
- ZNF532 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs367934703, COSV60172282; called by muse, mutect2, varscan2
- ZNF835 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs755139450, COSV73379292; called by muse, mutect2, varscan2
- ARID5B | c.1623_1624del p.L542Pfs*26 | Frame Shift Del (DEL) | VAF 60/169 reads (36%) | called by mutect2, pindel, varscan2
- CHIC2 | c.377_380dup p.H128Ifs*16 | Frame Shift Ins (INS) | VAF 92/192 reads (48%) | called by mutect2, pindel, varscan2
- CHRDL1 | c.296del p.P99Qfs*2 (on ENST00000372045; = p.P105Qfs*2 on NM_145234.4) | Frame Shift Del (DEL) | VAF 186/479 reads (39%) | called by mutect2, pindel, varscan2
- COL13A1 | c.1232del p.P411Qfs*52 (on ENST00000398978 / NM_001130103.2; = p.P354Qfs*52 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/9 reads (67%) | called by mutect2, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 82/241 reads (34%) | called by mutect2, pindel, varscan2
- EIF3J | c.774_*1del | Nonstop Mutation (DEL) | VAF 142/345 reads (41%) | called by mutect2, varscan2
- ETV6 | c.844del p.R282Gfs*34 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel
- GDPD2 | c.619del p.L207Yfs*35 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- JAG1 | c.2173del p.D725Mfs*18 | Frame Shift Del (DEL) | VAF 49/124 reads (40%) | called by mutect2, pindel, varscan2
- MFSD9 | c.251_253del p.V84del | In Frame Del (DEL) | VAF 44/118 reads (37%) | called by pindel, varscan2
- MYO16 | c.3931dup p.S1311Ffs*3 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by mutect2, pindel
- NHS | c.3596del p.N1199Tfs*6 | Frame Shift Del (DEL) | VAF 186/533 reads (35%) | called by mutect2, pindel, varscan2
- NIPBL | c.7750del p.T2584Qfs*27 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | called by mutect2, pindel, varscan2
- PRRC2A | c.5052del p.K1685Rfs*9 | Frame Shift Del (DEL) | VAF 64/127 reads (50%) | called by mutect2, varscan2
- RAD54L | c.2081dup p.D695* | Frame Shift Ins (INS) | VAF 11/21 reads (52%) | called by mutect2, pindel, varscan2
- SIX5 | c.2134G>T p.G712C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- TRIM50 | c.446del p.K149Rfs*10 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | called by mutect2, varscan2
- VPS13C | c.5028_5029del p.Y1677Sfs*11 (on ENST00000644861 / NM_020821.3; = p.Y1634Sfs*11 on NM_017684.5) | Frame Shift Del (DEL) | VAF 52/524 reads (10%) | called by mutect2, pindel, varscan2
- WBP11 | c.262del p.T88Pfs*20 | Frame Shift Del (DEL) | VAF 64/163 reads (39%) | called by mutect2, pindel, varscan2
- ABCB6 | c.1824C>T p.D608= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1378354306, COSV54694218; called by muse, mutect2, varscan2
- AC098582.1 | c.204T>C p.H68= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV52018625; called by muse, mutect2, varscan2
- ADGRB3 | c.3357C>T p.A1119= | Silent (SNP) | VAF 99/231 reads (43%) | catalogued as COSV53238842, COSV99483836; called by muse, mutect2, varscan2
- BMP6 | c.1059C>T p.Y353= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs34004211; called by muse, mutect2, varscan2
- CIT | c.921C>A p.T307= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as COSV55863693; called by muse, mutect2, varscan2
- CLPTM1 | c.960C>A p.A320= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV61611462, COSV61612351; called by muse, mutect2, varscan2
- COL6A3 | c.5388G>A p.A1796= | Silent (SNP) | VAF 70/139 reads (50%) | catalogued as rs116565519, COSV55083844; called by muse, mutect2, varscan2
- DGAT2 | c.1131C>T p.F377= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs148751558; called by muse, mutect2
- ERP27 | c.705G>A p.L235= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as COSV56762730; called by muse, mutect2, varscan2
- EVC2 | c.1881C>T p.H627= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as rs1181526421, COSV60389870; called by muse, mutect2, varscan2
- FAT1 | c.13620C>T p.Y4540= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs773428259, COSV71673022; called by muse, mutect2, varscan2
- FLNA | c.6963C>T p.F2321= (on ENST00000369850 / NM_001110556.2; = p.F2313= on NM_001456.3) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV61039067; called by muse, mutect2, varscan2
- GARNL3 | c.2235C>T p.F745= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as COSV59224716; called by muse, mutect2, varscan2
- GRK4 | c.846C>T p.P282= (on ENST00000398052 / NM_182982.3; = p.P250= on NM_005307.3) | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as rs141637189; called by muse, mutect2, varscan2
- GRM6 | c.2487G>A p.S829= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs202157072, COSV51437158; called by muse, mutect2, varscan2
- HIVEP2 | c.3285C>T p.G1095= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs371626242; called by muse, mutect2, varscan2
- HS3ST4 | c.1095C>T p.A365= | Silent (SNP) | VAF 124/298 reads (42%) | catalogued as rs370272330, COSV100502541; called by muse, mutect2, varscan2
- IGFBP2 | c.732G>A p.P244= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs771107802, COSV52079778, COSV52080697; called by muse, mutect2, varscan2
- JADE2 | c.1272C>T p.V424= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as rs372627663; called by muse, mutect2
- KRT80 | c.1344G>A p.S448= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as rs146327143; called by muse, mutect2, varscan2
- MAGEA12 | c.780G>A p.Q260= | Silent (SNP) | VAF 11/325 reads (3%) | catalogued as COSV100757030; called by muse, mutect2
- MAT1A | c.261C>T p.I87= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV64745056; called by muse, mutect2, varscan2
- MUC3A | c.8289T>C p.L2763= | Silent (SNP) | VAF 90/400 reads (23%) | catalogued as COSV60212741; called by muse, mutect2, varscan2
- MYLK | c.3843C>T p.S1281= | Silent (SNP) | VAF 112/204 reads (55%) | catalogued as rs377231739; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- NFASC | c.2046C>T p.P682= (on ENST00000339876 / NM_001378329.1; = p.P678= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs768250957, COSV58361844, COSV58379379; called by muse, mutect2, varscan2
- NOS2 | c.1209G>A p.T403= | Silent (SNP) | VAF 126/255 reads (49%) | catalogued as rs201958569, COSV58222571; called by muse, mutect2, varscan2
- NRP2 | c.1383C>T p.S461= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as rs751890151, COSV55925597; called by muse, mutect2, varscan2
- OPN1SW | c.489C>T p.G163= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1413048027, COSV50821394; called by muse, mutect2, varscan2
- PALMD | c.972G>A p.P324= | Silent (SNP) | VAF 95/228 reads (42%) | catalogued as rs145694277; called by muse, mutect2, varscan2
- PCDHB4 | c.555T>C p.S185= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV52020778; called by muse, mutect2, varscan2
- PRELP | c.183C>T p.P61= | Silent (SNP) | VAF 103/304 reads (34%) | catalogued as COSV58115343; called by muse, mutect2, varscan2
- PRKN | c.768C>T p.R256= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV58210051; called by muse, mutect2, varscan2
- SEC14L1 | c.1659C>T p.F553= | Silent (SNP) | VAF 40/99 reads (40%) | catalogued as rs145965497, COSV66721374; called by muse, mutect2, varscan2
- SEC31B | c.2016G>A p.Q672= | Silent (SNP) | VAF 8/125 reads (6%) | catalogued as COSV100947449; called by muse, mutect2
- SF3B2 | c.327A>G p.P109= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- SIPA1 | c.2781C>T p.D927= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs753174536, COSV58014170; called by muse, mutect2, varscan2
- SLC9C2 | c.558A>G p.G186= | Silent (SNP) | VAF 11/167 reads (7%) | catalogued as COSV100876989; called by muse, mutect2
- STK11IP | c.2757C>T p.V919= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1464457553; called by muse, mutect2
- TBC1D5 | c.591C>T p.N197= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs544749999, COSV53752542; called by muse, mutect2, varscan2
- TBL1X | c.1665C>T p.N555= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs756216237, COSV54277016; called by muse, mutect2, varscan2
- TMEM53 | c.342C>T p.N114= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs773405213, COSV62406155; called by muse, mutect2
- TMEM71 | c.246C>T p.C82= | Silent (SNP) | VAF 159/308 reads (52%) | catalogued as rs183699304, COSV63456526; called by muse, mutect2, varscan2
- TTC7B | c.1575T>C p.L525= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as COSV60627358; called by muse, mutect2, varscan2
- UBC | c.1641C>T p.L547= | Silent (SNP) | VAF 49/160 reads (31%) | catalogued as rs1071864, COSV100299118; called by muse, mutect2, varscan2
- UBC | c.1413C>T p.L471= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as rs1399576513, COSV60058825; called by muse, mutect2, varscan2
- UNC79 | c.4419G>A p.T1473= (on ENST00000393151 / NM_001346218.2; = p.T1296= on NM_020818.5) | Silent (SNP) | VAF 114/276 reads (41%) | catalogued as rs755525028, COSV56379629; called by muse, mutect2, varscan2
- UPF3A | c.1095C>T p.D365= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs3993412; called by muse, mutect2, varscan2
- VPS13C | c.768C>T p.S256= (on ENST00000644861 / NM_020821.3; = p.S213= on NM_017684.5) | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs368498429; called by muse, mutect2
- ZFP3 | c.768T>C p.N256= | Silent (SNP) | VAF 15/153 reads (10%) | catalogued as COSV100603883; called by muse, mutect2
- ZNF25 | c.336T>C p.H112= | Silent (SNP) | VAF 15/199 reads (8%) | called by muse, mutect2
- ZNF609 | c.63C>T p.Y21= | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as rs967793472, COSV100441645; called by muse, mutect2
- AL136982.4 | n.523C>A | RNA (SNP) | VAF 182/394 reads (46%) | called by muse, mutect2, varscan2
- DNM3 | c.1689+13329G>A | Intron (SNP) | VAF 137/219 reads (63%) | catalogued as COSV62455193; called by muse, mutect2, varscan2
- ERCC4 | c.*1A>G | 3'UTR (SNP) | VAF 21/181 reads (12%) | catalogued as COSV100319085; called by muse, mutect2, varscan2
- FBXW7 | c.502-2432C>T | Intron (SNP) | VAF 19/144 reads (13%) | catalogued as rs751929497, COSV55902848; called by muse, mutect2, varscan2
- HERC2P3 | n.2011C>T | RNA (SNP) | VAF 21/65 reads (32%) | catalogued as rs1160677325; called by mutect2, varscan2
- MAP4 | c.1999+5025C>G | Intron (SNP) | VAF 136/265 reads (51%) | catalogued as rs764462832, COSV53136356; called by muse, mutect2, varscan2
- PGM1 | c.247-5666G>T | Intron (SNP) | VAF 29/78 reads (37%) | catalogued as COSV64300268; called by muse, mutect2, varscan2
- TTBK2 | c.823-6315T>C | Intron (SNP) | VAF 11/108 reads (10%) | catalogued as COSV51158170; called by muse, mutect2, varscan2
- XIRP2 | c.*903C>T | 3'UTR (SNP) | VAF 10/157 reads (6%) | catalogued as COSV99746777; called by muse, mutect2
